MMRF case MMRF_2497 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4535b9a6-15a2-4ef9-bf54-412e173a8433

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.1 years (25,622 days); ISS stage: I; Days to last known disease status: 686 days (1.9 years); Days to last follow up: 686 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 30 days; Days to treatment end: 223 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 240 days; Days to treatment end: 490 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 511 days (1.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -28 (ECOG 0): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 30 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.106 mg/dL; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 1.63 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 9.3 g/dL; Glucose 6.33 mmol/L; C-Reactive Protein 0.05 mg/dL.
- Day 58 (ECOG 0): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 40.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.654 mg/dL; Lactate Dehydrogenase 1.28 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 8.5 g/dL; Glucose 6.99 mmol/L.
- Day 148 (ECOG 0): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.199 mg/dL; Lactate Dehydrogenase 1.13 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.1 mmol/L; Albumin 31 g/L; Total Protein 8.1 g/dL; Glucose 6.16 mmol/L.
- Day 239 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.625 mg/dL; Immunoglobulin G 3.12 g/L; Immunoglobulin A 26.4 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 1.4 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 295 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 7.9 g/dL; Glucose 6.6 mmol/L.
- Day 329 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 4.02 g/L; Immunoglobulin A 27.5 g/L; Immunoglobulin M 0.105 g/L; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 8.7 g/dL; Glucose 6.66 mmol/L.
- Day 413 (ECOG 1): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.812 mg/dL; Immunoglobulin G 3.46 g/L; Immunoglobulin A 21.2 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 284 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 7.5 g/dL; Glucose 5.72 mmol/L.
- Day 518 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.703 mg/dL; Immunoglobulin G 3.44 g/L; Immunoglobulin A 27.3 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 1.48 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 283 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 8.6 g/dL; Glucose 4.46 mmol/L.
- Day 630 (ECOG 2): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.719 mg/dL; Immunoglobulin G 3.26 g/L; Immunoglobulin A 22.1 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.77 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 286 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 7.8 g/dL; Glucose 5.72 mmol/L.
- Day 686 (ECOG 2): Immunoglobulin G 3.49 g/L; Immunoglobulin A 16.1 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 325 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 8 g/dL; Glucose 6 mmol/L.

Other clinical attributes
- Day -28: Weight: 50 kg; Height: 168 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2497_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -28 days.
- Sample MMRF_2497_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -28 days.
